Surgical pathology report (de-identified scan), TCGA case TCGA-S7-A7WV, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site University Hospital Motol, specimen TCGA-S7-A7WV-01A (Primary Tumor).

Gross:

Left adrenal gland with tumor (weight 219g, dimensions 120x80x55 mm). Tumor is encapsulated, on cut with large hemorrhages. Material was procured in five blocks.

Micro:

Pheochromocytoma with large necroses with only focally preserved vital tumorous structures. Cellulization with granular neutrophils, siderophagic cleaning reaction (Fe), and focally beginning fibrotization are present on the border of necrotic foci.

Vital adrenal cortex is focally subcapsular which is followed by fibrous and fatty hemorrhagic capsula. Blocks D, E contain necrotic a hemorrhagic tumorous tissue in more than 90% cut surface.

Imunohistochemic examination:

Chromogranin is in tissue strongly positive, adrenal cortex and periadrenal adipose tissue with reactive fibrosis and posthemorrhagic cleaning reaction are negative. MIB1 3-5% tumor cell nuclei positive

CD34, FVIII - no angioinvasion was found

S100 – sustentacular cells only sporadically positive

PASS:

Large nests or diffuse growth (>10% of tumor volume) 2

Central (middle of large nests) or confluent tumor necrosis 2

High cellularity

Cellular monotony

Tumor cell spindling (even if focal) 2

Mitotic figures >3/10 HPF

Atypical mitotic figure(s)

Extension into adipose tissue

Vascular invasion

Capsular invasion 1

Profound nuclear pleomorphism

Nuclear hyperchromasia 1

Total 8

Procurement date:

Confirmation date:

ICD-O-3
Pheochromocytoma, malignant
8700/3
Site (Adrenal gland) NOS
C74.9
JW 10/9/13

Source: NCI Genomic Data Commons file 51d21535-434e-4a15-8a32-27af5b03b72c (TCGA-S7-A7WV.58016AE9-B1CF-4D33-88AA-71E444D45AB1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).